Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6955, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6955-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (A) RIGHT MAXILLARY SINUS:
Bone, no tumor.
- [REDACTED]
- [REDACTED]

DIAGNOSIS

- (A) RIGHT MAXILLARY SINUS:
Tissue submitted for decalcification, supplemental report will follow.
- (B) RIGHT INFRA-STRUCTURE MAXILLARY:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA, 6.0 MM IN DEPTH, PRESENCE OF LYMPHATIC INVASION IS NEGATIVE.
- (C) RIGHT INFERIOR TURBINATE:
Respiratory mucosa, no tumor present.
- (D) RIGHT CHEEK MARGIN:
Squamous mucosa, no tumor present.
- (E) RIGHT SOFT PALATE MARGIN:
Squamous mucosa, no tumor.
- (F) HARD PALATE MARGIN:
Squamous mucosa, no tumor.
- (G) ANTERIOR GUM MARGIN:
Squamous mucosa, no tumor present.
- [REDACTED]
- [REDACTED]

GROSS DESCRIPTION

- (A) RIGHT MAXILLARY SINUS - Fragments of thin, bony tissue submitted for decalcification under A. [REDACTED]
- (B) RIGHT INFRA-STRUCTURE MAXILLARY - A portion of bone and soft tissue with

Page 1 of 2

[page 2 of 2]
[REDACTED]

overall measurements of 5.0 x 2.5 x 2.0 cm. An ulcerated and friable mass measuring 2.5 x 1.5 x 0.6 cm is noted. The ascending mucosal margin is seen surrounding the ulcerated lesion. No visible or felt bony erosion is identified. The specimen is submitted sequentially from one side to the other under B1 to B10. [REDACTED]

(C) RIGHT INFERIOR TURBINATE - A small mucosal and soft tissue fragment, 2.0 x 0.5 x 1.0 cm. No identifiable lesion is noted. The specimen is submitted under C1 and C2. [REDACTED]

(D) RIGHT CHEEK MARGIN - A strip of tan-pink, glistening mucosa (1.0 x 0.3 x 0.2 cm). Submitted entirely for frozen section in D. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(E) RIGHT SOFT PALATE MARGIN - Two fragments of tan-pink portions of mucosal tissue (0.5 x 0.2 x 0.2 cm and 0.3 x 0.3 x 0.3 cm). Submitted entirely for frozen section in E. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(F) HARD PALATE MARGIN - A strip of tan-pink, glistening mucosa (0.7 x 0.3 x 0.2 cm). Submitted for frozen section in F. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

(G) ANTERIOR GUM MARGIN - A strip of tan-pink, glistening mucosa (0.7 x 0.3 x 0.2 cm). Submitted for frozen section in G. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

SNOMED CODES

M-80703 T-51800

Source: NCI Genomic Data Commons file 1a854fa5-0d84-4a2e-838a-e4828dd1ddbe (TCGA-CV-6955.6099DBEC-156F-406C-879B-64900DEE8C14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).